CCDI case PBCHPI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/488e4660-2959-4ce2-8ce5-e7011a4ec202

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,524 days).

Biospecimens (3 samples)
- Samples 0DS9ZW, 0DSA07 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSA0S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
